Somatic mutation profile of tumor specimen TARGET-10-PASWNU-09A (aliquot TARGET-10-PASWNU-09A-01D) from TARGET case TARGET-10-PASWNU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,580 days).
Specimen TARGET-10-PASWNU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 742b927c-a041-48c3-b1e5-1202afb4a0a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASWNU-10A (Blood Derived Normal), aliquot TARGET-10-PASWNU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7670bd15-6e51-4797-b514-edc29e2bb1be

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Nonsense Mutation 7, Intron 5, 3'UTR 2, In Frame Ins 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 39/113 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 29/53 reads (55%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, mutect2, varscan2
- SCN1A | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918770, CD032498, CM031732, CM159412, COSV57670403, COSV57693028; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.3431G>T p.R1144L (on ENST00000265723 / NM_018849.3; = p.R1137L on NM_000443.4) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55943540; called by muse, mutect2, varscan2
- ARHGEF6 | c.1850A>T p.K617M | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV51697483; called by muse, mutect2, varscan2
- BBS12 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV58563447; called by muse, mutect2, varscan2
- C11orf68 | c.17_18delinsGGCCGGGCTTCATTCCC p.E6delinsGPGFIP (on ENST00000530188; = p.E47delinsGPGFIP on NM_031450.4) | In Frame Ins (INS) | VAF 10/34 reads (29%) | catalogued as COSV56990174; called by pindel, varscan2*
- CLDN18 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764565705, COSV51735796; called by muse, mutect2
- CSMD3 | c.5279C>T p.A1760V (on ENST00000297405 / NM_001363185.1; = p.A1656V on NM_052900.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs761014904, COSV52214486; called by muse, mutect2, varscan2
- DLG5 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs750921859, COSV64950564; called by muse, mutect2, varscan2
- EGLN1 | c.761A>T p.D254V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64150403, COSV64150989; called by muse, mutect2, varscan2
- FAM160A2 | c.1502G>A p.R501H (on ENST00000449352 / NM_001098794.2; = p.R515H on NM_032127.4) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs199932613, COSV56414542; called by muse, mutect2, varscan2
- FBXO28 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV64800209; called by muse, mutect2
- FBXW7 | c.2009G>A p.G670E (on ENST00000281708 / NM_001349798.2; = p.G590E on NM_018315.5) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55914320, COSV55931646; called by muse, mutect2
- FCSK | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs757838629, COSV55376935; called by muse, mutect2, varscan2
- FSIP2 | c.5094G>A p.M1698I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs752281133, COSV58105352; called by muse, mutect2, varscan2
- GABRA6 | c.269A>C p.E90A | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV50901083; called by muse, mutect2, varscan2
- HUWE1 | c.12448G>T p.D4150Y | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53359894, COSV53369009; called by muse, mutect2, varscan2
- KLHDC8A | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as rs772941527, COSV65679537; called by muse, mutect2, varscan2
- KMT2A | c.4069C>T p.Q1357* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV63294868; called by muse, mutect2, varscan2
- MAG | c.1005G>C p.M335I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV62703791; called by mutect2, varscan2
- MED15 | c.1588C>T p.Q530* (on ENST00000263205 / NM_001003891.3; = p.Q490* on NM_015889.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV53035103; called by muse, mutect2
- MUC5AC | c.3313G>A p.A1105T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.25); catalogued as rs1010764588; called by muse, mutect2
- NAT2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as rs1243197391, COSV54063403; called by muse, mutect2, varscan2
- NOTCH1 | c.4775T>C p.F1592S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024854, COSV53033159; called by muse, mutect2, varscan2
- PCYOX1L | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV51006531; called by muse, mutect2, varscan2
- PPFIBP2 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs1034895327, COSV55081370; called by muse, mutect2, varscan2
- RIMKLB | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); catalogued as rs1565430782, COSV55240951; called by muse, mutect2, varscan2
- ROS1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780553416, COSV63860043; called by muse, mutect2, varscan2
- RPL5 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as CM1313012, COSV59872943; called by muse, mutect2
- SCN9A | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV57612703, COSV57629889; called by muse, mutect2, varscan2
- SEC62 | c.880_881insGGAGCCTGA p.L293_K294insRSL | In Frame Ins (INS) | VAF 14/68 reads (21%) | catalogued as COSV61262524; called by mutect2, pindel*, varscan2*
- SH2B3 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953911126, COSV57981192; called by muse, mutect2, varscan2
- SLC13A1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52018562; called by muse, mutect2, varscan2
- SMOC2 | c.1139G>A p.R380H (on ENST00000356284 / NM_001166412.2; = p.R391H on NM_022138.3) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs529365137, COSV62441946; called by muse, mutect2, varscan2
- SPRTN | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV50480636; called by muse, mutect2, varscan2
- TRIM32 | c.1630C>A p.H544N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.221); catalogued as COSV57827910; called by muse, mutect2, varscan2
- UNC5D | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54846900, COSV99778300; called by muse, mutect2, varscan2
- USP1 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51998352; called by muse, mutect2, varscan2
- CD276 | c.773C>A p.A258D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRRC56 | c.836A>G p.E279G | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2
- NCR3LG1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHRR | c.1869C>T p.D623= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs539730239, COSV57094822; called by muse, mutect2
- EVC2 | c.3051C>T p.H1017= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- FASTKD1 | c.2289C>T p.I763= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs571026222, COSV71624119; called by muse, mutect2
- GREM1 | c.57G>T p.L19= | Silent (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- KCND2 | c.1782T>C p.T594= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as rs372964925; called by muse, mutect2, varscan2
- NUP160 | c.645C>T p.T215= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs146827628; called by muse, mutect2, varscan2
- OR2T1 | c.483C>A p.I161= | Silent (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- OR9Q2 | c.132C>A p.G44= | Silent (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- SSTR1 | c.96C>A p.A32= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs772211121; called by muse, varscan2
- TAS2R9 | c.345G>A p.S115= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs143855266; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918812 G>A | 5'Flank (SNP) | VAF 16/42 reads (38%) | catalogued as COSV62706635; called by muse, mutect2, varscan2
- DNAH9 | c.10971+714G>T | Intron (SNP) | VAF 22/36 reads (61%) | called by muse, mutect2, varscan2
- GDAP1L1 | c.*419G>T | 3'UTR (SNP) | VAF 44/103 reads (43%) | called by muse, mutect2, varscan2
- HAUS4 | c.-159C>T | 5'UTR (SNP) | VAF 6/8 reads (75%) | catalogued as COSV52827341; called by mutect2, varscan2
- PDHA1 | c.57+2454C>T | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- SEC14L1 | c.1612-36G>A | Intron (SNP) | VAF 8/14 reads (57%) | catalogued as rs1178741522; called by muse, mutect2, varscan2
- SULT1C2 | c.*62C>A | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- SYT3 | c.1707+48C>T | Intron (SNP) | VAF 11/14 reads (79%) | catalogued as rs778564524; called by muse, mutect2, varscan2
- TENM2 | c.713-31C>T | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
